Somatic mutation profile of tumor specimen TCGA-H6-A45N-01A (aliquot TCGA-H6-A45N-01A-11D-A26I-08) from TCGA case TCGA-H6-A45N, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-H6-A45N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1630f3cb-a4ba-47cb-8802-765459fce547.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H6-A45N-10A (Blood Derived Normal), aliquot TCGA-H6-A45N-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73fb9cd8-f515-40ec-871e-744dbdc6f659

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 78/335 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.3706A>G p.T1236A | Missense Mutation (SNP) | VAF 76/1742 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1307887571, COSV99796180; called by muse, mutect2
- ANKMY2 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV100187223; called by muse, mutect2
- CD5L | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 36/832 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1307024327, COSV100941106; called by muse, mutect2
- DCPS | c.187T>A p.F63I | Missense Mutation (SNP) | VAF 23/427 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV55011695, COSV99703531; called by muse, mutect2
- GARS1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 48/1235 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV66828321; called by muse, mutect2
- KCNH7 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 15/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036992, COSV59804752; called by muse, mutect2
- MGAM | c.3931C>T p.R1311W | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs573145045, COSV72074409; called by muse, mutect2
- MMP1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 28/616 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.089); catalogued as rs868735707, COSV59510969; called by muse, mutect2
- NRN1 | c.163G>C p.G55R | Missense Mutation (SNP) | VAF 54/720 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV99784237; called by muse, mutect2
- PIEZO2 | c.7704G>T p.M2568I | Missense Mutation (SNP) | VAF 26/537 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99555280; called by muse, mutect2
- PPP1R12C | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 76/726 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs768490350, COSV99670306; called by muse, mutect2, varscan2
- RPRD2 | c.3248C>G p.A1083G | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV100955254; called by muse, mutect2
- TRPC6 | c.1085A>T p.N362I | Missense Mutation (SNP) | VAF 34/953 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV100723721; called by muse, mutect2
- TUT4 | c.2405C>T p.T802I | Missense Mutation (SNP) | VAF 44/975 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99932612; called by muse, mutect2
- UNC13B | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 32/756 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV101037012; called by muse, mutect2
- VAC14 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99934885; called by muse, mutect2
- ZBTB45 | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs775591124, COSV100657763; called by muse, mutect2
- ZNF224 | c.1950G>C p.K650N | Missense Mutation (SNP) | VAF 22/666 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV100425466; called by muse, mutect2
- PSMB1 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 18/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GFRA2 | c.405C>T p.L135= | Silent (SNP) | VAF 38/995 reads (4%) | called by muse, mutect2
- PCARE | c.522G>A p.V174= | Silent (SNP) | VAF 18/564 reads (3%) | called by muse, mutect2
- PRKACA | c.654G>A p.K218= | Silent (SNP) | VAF 23/371 reads (6%) | catalogued as COSV100432176; called by muse, mutect2
- TMEM14B | c.264C>T p.F88= | Silent (SNP) | VAF 24/420 reads (6%) | catalogued as COSV101077475; called by muse, mutect2
